Somatic mutation profile of tumor specimen TCGA-CS-5396-01A (aliquot TCGA-CS-5396-01A-02D-1468-08) from TCGA case TCGA-CS-5396, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 53.1 years (19,399 days).
Specimen TCGA-CS-5396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2381b7d2-79d9-48fc-8326-bdbcc3952040.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5396-10A (Blood Derived Normal), aliquot TCGA-CS-5396-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/157b6398-6dc1-4910-9a7d-f6e56ff3cada

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/100 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs193929331, CM073168, COSV55502396; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.232); catalogued as COSV52024095; called by muse, mutect2, varscan2
- ADGRA2 | c.2934G>T p.R978S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.119); catalogued as COSV55105394; called by muse, mutect2, varscan2
- ATP8B2 | c.734G>A p.S245N (on ENST00000672630; = p.S212N on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV59248499; called by muse, mutect2
- COL4A6 | c.4162G>A p.D1388N | Missense Mutation (SNP) | VAF 127/317 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.542); catalogued as rs1015479705, COSV57871116, COSV57876236; called by muse, mutect2, varscan2
- CSH1 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60242952; called by muse, mutect2, varscan2
- CYCS | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV59872938; called by muse, mutect2, varscan2
- EEA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs557361655, COSV59285114; called by muse, mutect2, varscan2
- EPHA7 | c.2422A>G p.I808V | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV65190494; called by muse, mutect2, varscan2
- MAP3K5 | c.2177T>C p.I726T | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300181141, COSV62891927; called by muse, mutect2, varscan2
- MRC1 | c.3793C>T p.R1265* | Nonsense Mutation (SNP) | VAF 16/562 reads (3%) | catalogued as rs1213618358; called by muse, mutect2
- MTA2 | c.889T>C p.W297R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53874514; called by muse, mutect2, varscan2
- MTOR | c.6647T>C p.L2216P | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV63877547; called by muse, mutect2, varscan2
- NEB | c.14620C>T p.R4874C | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757108531, COSV51441850; called by muse, mutect2, varscan2
- PDE1B | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV54495782; called by muse, mutect2
- PLXNA3 | c.3275G>T p.R1092L | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV63754636, COSV63755502; called by muse, mutect2, varscan2
- SLC26A8 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs200862862; called by muse, mutect2, varscan2
- SLC6A6 | c.1550T>C p.V517A | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200367448, COSV62652337; called by muse, mutect2, varscan2
- SPATA31E1 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.735); catalogued as rs531419008, COSV57790676; called by muse, mutect2
- TENM1 | c.2483G>A p.C828Y | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64441418; called by muse, mutect2, varscan2
- THOP1 | c.1746G>T p.E582D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV57020882; called by muse, mutect2, varscan2
- TIAM1 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54571786; called by muse, mutect2, varscan2
- KAT6B | c.3835del p.T1279Hfs*9 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- ADH1A | c.369C>T p.T123= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52924660, COSV52926033; called by muse, mutect2, varscan2
- DNPH1 | c.297G>A p.L99= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV52733945; called by muse, mutect2, varscan2
- EFNB2 | c.516A>T p.G172= | Silent (SNP) | VAF 98/220 reads (45%) | catalogued as COSV55367247; called by muse, mutect2, varscan2
- FRY | c.2223A>C p.V741= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV66578857; called by muse, mutect2, varscan2
- GADL1 | c.735T>C p.G245= | Silent (SNP) | VAF 86/204 reads (42%) | catalogued as COSV56984886; called by muse, mutect2, varscan2
- PHEX | c.510T>A p.L170= | Silent (SNP) | VAF 155/428 reads (36%) | catalogued as COSV65078421; called by muse, mutect2, varscan2
- ESCO1 | c.1954-670G>A | Intron (SNP) | VAF 11/18 reads (61%) | catalogued as rs369884269; called by muse, mutect2, varscan2
